Surgical pathology report (de-identified scan), TCGA case TCGA-G3-A6UC, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Alberta Health Services, specimen TCGA-G3-A6UC-01A (Primary Tumor).

[page 1 of 2]
CONFIDENTIAL

SURGICAL PATHOLOGY REPORT

Time Collected

Time Reported

Order Number

Status

Final

Time Received

Time Transmitted

Ordering Provider

Relevant Information

Location

Copied To

Report Patient

Demographics (for
verification purposes)

Sex: M

ICD-O-3

C60
path Carcinoma, hepatocellular
8170/3
Carcinoma, hepatocellular NC
Solid variant (8170/3)
(8230/3)

Code to highest 8230/3

Site Liver C22.0

QW 7/22/13

SURGICAL PATHOLOGY REPORT

*****Surgical Pathology Report*****

Accession Number
Collected Date/Time
Received Date/Time
Pathologist

Specimen Description
A. Gallbladder at
B. Liver segment 6 at

Clinical Information
Cirrhosis secondary to ETOH with likely HCC.

Diagnosis

A. Gallbladder:

- Cholelithiasis.

B. Liver segment 6:

- Chronic hepatitis, mild.
- Cirrhosis, micronodular.
- Hepatocellular carcinoma, moderately differentiated, solid variant, 2.5 cms in the greatest dimension, with metastases to the portal veins and intrahepatic metastases
Tumor 0.3 cm away from the resection margin.

Reported by:

Electronically signed by

Verified:

Gross Description

Received are specimen containers A to B. All requisitions and specimen containers are
labelled with the patient's name, The cassettes and AP identifiers are
labelled with the Surgical Number

A. Specimen is received fresh. The container is designated "A. Gallbladder". The

[page 2 of 2]
specimen consists of a congested intact gallbladder measuring 11.0 x 3.5 x 3.5 cm. The serosal surface is smooth and glistening. Opening reveals the gallbladder to be filled with green bile. Also found in the gallbladder are five black irregular calculi ranging from 0.4 cm up to 1.5 cm in greatest dimension. The mucosal surface is dark green, rough and the gallbladder wall averages between 0.1 to 0.2 cm in thickness. Found at the neck and near the cystic duct are two firm palpable nodules within the adipose tissue, the first measuring 1.0 cm, the other 1.5 cm in greatest dimension. Sections are as follows:

A1 - three sections of gallbladder.

A2 - the smaller node bisected.

A3 - the larger node bisected.

B. Specimen is received fresh. The container is designated "Liver segment 6". The specimen consists of a portion of liver weighing 50.8 g and measuring 6.5 x 5.0 x 2.5 cm. The liver capsule is nodular and the surgical resection margin has been inked blue. Sectioning reveals a green circumscribed mass measuring 2.5 x 2.3 x 2.5 cm. Adjacent to the green circumscribed mass is a hemorrhagic circumscribed mass measuring 1.0 x 1.0 x 1.0 cm. The green mass comes within 0.3 cm of the blue painted surgical resection margin and the hemorrhagic mass 0.1 cm to the blue painted surgical resection margin. The green mass comes with less than 0.1 cm of the liver capsule and the hemorrhagic mass comes within 0.7 cm of the liver capsule. Sections are as follows:

B1 - section of the green mass and its relationship to the liver capsule.

B2 - section of the green mass and its relationship to the blue painted surgical resection margin.

B3 - hemorrhagic mass with a portion of the adjacent green mass and the relationship to the blue painted surgical margin.

B4 - further section of hemorrhagic mass and relationship to blue painted surgical resection margin.

Please note that upon sectioning of the hemorrhagic mass, it is found to have a cut surface which is granular and the substance easily pulls out of the circumscribed area, query blood vessel.

B5 - representative section of liver parenchyma.

Accession Number
Encounter Number
Patient Location

Prior Malignancy History	Prostate	

Source: NCI Genomic Data Commons file 7c778bf5-16d2-43cd-aa09-e6170f091198 (TCGA-G3-A6UC.08415C4C-C645-4911-BA53-6E562E562FD4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).